Somatic mutation profile of tumor specimen TCGA-BG-A0MA-01A (aliquot TCGA-BG-A0MA-01A-11D-A17D-09) from TCGA case TCGA-BG-A0MA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 60.3 years (22,036 days).
Specimen TCGA-BG-A0MA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90c23412-f0a7-40bc-bbed-4b54e37769c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MA-11A (Solid Tissue Normal), aliquot TCGA-BG-A0MA-11A-11D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b2b2b6c-2885-4fff-a5d6-78ef56967962

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 26, Silent 11, Frame Shift Del 5, Frame Shift Ins 3, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.6049C>T p.R2017W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587784176, CM031305, COSV100728999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs121909227, CM981672, COSV64290622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAT2 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as rs762303976, COSV99395761; called by muse, mutect2, varscan2
- APBA2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.311); catalogued as rs1379131912, COSV101381803, COSV68792774, COSV68795881; called by muse, mutect2
- BAAT | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV52291174; called by muse, mutect2, varscan2
- CNTNAP3 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV99904752; called by muse, mutect2
- EP300 | c.4115G>A p.C1372Y | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs760707534, COSV54343747; called by muse, mutect2, varscan2
- GARNL3 | c.3005C>T p.T1002M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs758873701, COSV59223670; called by muse, mutect2, varscan2
- GLYATL2 | c.764C>G p.P255R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99780362; called by muse, mutect2, varscan2
- HDX | c.80G>C p.S27T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99947216; called by muse, mutect2, varscan2
- HECW1 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as rs1308383517, COSV101223464; called by muse, mutect2, varscan2
- HNRNPUL1 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as COSV99647236; called by muse, mutect2, varscan2
- KCNN4 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53454697, COSV99487045; called by muse, mutect2, varscan2
- LPA | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100306913; called by muse, mutect2, varscan2
- MAN2B2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs772632113, COSV53453968; called by muse, mutect2, varscan2
- NSD1 | c.1727dup p.N576Kfs*8 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs1299932363; called by pindel, varscan2
- P2RX7 | c.962T>G p.V321G | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99947550; called by muse, mutect2
- PDGFRA | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs779332376, COSV57271921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POP1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs757141424, COSV62892845; called by muse, varscan2
- PPIE | c.384+1G>A p.X128_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100180057; called by muse, mutect2, varscan2
- PTEN | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1564568473, COSV64302345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPS5 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as COSV99544925; called by muse, mutect2, varscan2
- RYR1 | c.8310+1del | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as COSV62105393; called by mutect2, pindel, varscan2
- SACS | c.5608G>A p.V1870M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as rs752750902, COSV101207418; called by muse, varscan2
- SLCO5A1 | c.1873A>G p.I625V | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.191); catalogued as COSV99479948; called by muse, mutect2, varscan2
- TAS2R14 | c.655T>C p.S219P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.151); catalogued as COSV101114749; called by muse, mutect2, varscan2
- TLR9 | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs5743846; called by muse, mutect2, varscan2
- TRAPPC9 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101227383; called by muse, mutect2, varscan2
- TRIO | c.2264A>G p.N755S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100710319; called by muse, mutect2, varscan2
- TRPC4 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs780518092, COSV100156442; called by muse, mutect2, varscan2
- YTHDC2 | c.1697T>C p.L566P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.761); catalogued as COSV99363259; called by muse, mutect2
- ADGRL1 | c.199del p.D67Tfs*110 (on ENST00000340736 / NM_001008701.3; = p.D67Tfs*105 on NM_014921.5) | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- ARID1A | c.2381_2390del p.G794Vfs*36 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | called by mutect2, pindel, varscan2
- KCNH8 | c.1393del p.V465Cfs*5 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- KMT2D | c.14107_14108dup p.D4703Efs*95 | Frame Shift Ins (INS) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- RAD54L2 | c.2966del p.Q989Rfs*10 | Frame Shift Del (DEL) | VAF 3/18 reads (17%) | called by mutect2, pindel*
- SIK2 | c.739dup p.L247Pfs*23 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- ABCC1 | c.3063C>T p.A1021= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100579492; called by muse, mutect2
- AMPD2 | c.1029G>A p.E343= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99857685; called by muse, mutect2, varscan2
- IQSEC1 | c.2388C>T p.N796= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs745809088, COSV56223562, COSV99831836; called by muse, mutect2, varscan2
- MAB21L2 | c.741A>G p.R247= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100462144; called by muse, mutect2, varscan2
- NSUN4 | c.57G>T p.A19= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100197497; called by muse, mutect2
- PRMT1 | c.1092C>T p.C364= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99773427; called by muse, mutect2, varscan2
- SETD2 | c.3513A>T p.T1171= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100338924; called by muse, mutect2, varscan2
- TMC4 | c.1485C>T p.V495= (on ENST00000617472 / NM_001145303.3; = p.V489= on NM_144686.4) | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1259751416, COSV99713847; called by muse, mutect2, varscan2
- TPO | c.2655G>A p.S885= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs756050827, COSV61101520; called by muse, mutect2, varscan2
- TRIP11 | c.5250T>G p.L1750= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99970653; called by muse, mutect2, varscan2
- TSPO | c.375C>T p.A125= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as rs747530187, COSV99333417; called by muse, mutect2, varscan2
